TARGET case TARGET-40-NAAWGI — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/3c0c8332-2c95-53f8-8879-23bd51c433c0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Bone, NOS; Age at diagnosis: 38.0 years (13,870 days).

Biospecimens (1 sample)
- Sample TARGET-40-NAAWGI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
